Somatic mutation profile of tumor specimen 0DS292 from CCDI case PBCHPH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.9 years (1,777 days).
Specimen 0DS292: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4af086a9-ac33-4f27-a72a-6bdca8e398ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS29U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be6feb15-5193-40f3-a564-e7613562bff9

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 2, Frame Shift Del 1, 5'UTR 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNND2 | c.3007C>A p.P1003T | Missense Mutation (SNP) | VAF 53/476 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.075); catalogued as rs762883023; called by muse, mutect2, varscan2
- CTPS2 | c.1633C>A p.L545I | Missense Mutation (SNP) | VAF 349/829 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63722810; called by muse, mutect2, varscan2
- FBN3 | c.6881-1G>T p.X2294_splice | Splice Site (SNP) | VAF 21/580 reads (4%) | catalogued as rs868132452; called by muse, mutect2
- ACR | c.551A>T p.Y184F | Missense Mutation (SNP) | VAF 221/478 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CPEB4 | c.410del p.S137Ffs*4 | Frame Shift Del (DEL) | VAF 168/390 reads (43%) | called by mutect2, varscan2
- ITSN1 | c.5163G>A p.P1721= | Silent (SNP) | VAF 162/624 reads (26%) | catalogued as rs144206450; called by muse, mutect2, varscan2
- SPTA1 | c.2676A>G p.Q892= | Silent (SNP) | VAF 238/921 reads (26%) | called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 11/99 reads (11%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
- PHGDH | c.290+35G>C | Intron (SNP) | VAF 43/445 reads (10%) | called by muse, mutect2
- SPATA48 | c.-93T>G | 5'UTR (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
